Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A8HF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A8HF-01A (Primary Tumor).

[page 1 of 5]
REPORT

Collected:

Ordered by:

CLINICAL DIAGNOSIS:

Bladder cancer

FINAL DIAGNOSIS:

RADICAL CYSTECTOMY WITH URINARY DIVERSION TO SKIN GT PLACEMENT:

RIGHT URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO HIGH UROTHELIAL ATYPIA OR TUMOR IDENTIFIED

LEFT URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO HIGH GRADE UROTHELIAL ATYPIA OR TUMOR IDENTIFIED

PROSTATE AND BLADDER (C):

PROSTATE:

- BILATERAL PROSTATIC ADENOCARCINOMA, GLEASON' S SCORE 7 (3+4), EXTENDS INTO THE PROSTATIC CAPSULE BUT NOT THROUGH IT
- ALL MARGINS ARE FREE OF TUMOR
- PERINEURAL INVASION IDENTIFIED
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA, FREE OF TUMOR
- HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN III)

BLADDER:

- INVASIVE POORLY DIFFERENTIATED TRANSITIONAL CELL CARCINOMA (3.0 X 2.2 X 1.0 CM), GRADE 4/4, EXTENDING THROUGH THE LEFT POSTERIOR BLADDER WALL INTO PERIVESICAL TISSUE MICROSCOPICALLY
- NO LYMPHOVASCULAR TUMOR INVASION IDENTIFIED
- EXTENSIVE TUMOR NECROSIS LOCATED ADJACENT TO FUNGATING MASS LESION
- NO IN SITU CARCINOMA (FLAT LESION) IDENTIFIED
- MARGINS OF RESECTION, FREE OF UROTHELIAL ATYPIA AND TUMOR

LEFT LYMPH NODE CLOQUET (D):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

LEFT OBTURATOR LYMPH NODES (E):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES (0/4)

LEFT HYPOGASTRIC LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

PRESACRAL LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)

LEFT COMMON ILIAC LYMPH NODES (H):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

RIGHT LYMPH NODE OF CLOQUET (I):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

RIGHT OBTURATOR LYMPH NODE (J):

ICD O-3
Carcinoma, transitional cell NOS
8120/3
Site Bladder NOS C67.9
JW 1/23/14

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

RIGHT EXTERNAL ILIAC LYMPH NODE (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

RIGHT HYPOGASTRIC LYMPH NODE (L):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

RIGHT COMMON ILIAC LYMPH NODE (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODE (0/3)

LEFT PROXIMAL URETER (N):

- BENIGN URETER

- NO UROTHELIAL ATYPIA OR TUMOR IDENTIFIED

RIGHT PROXIMAL URETER (O):

- BENIGN URETER

- NO UROTHELIAL ATYPIA OR TUMOR IDENTIFIED

PATHOLOGIC TNM STAGE: Bladder cancer -pT3aNOMX

Prostate cancer-pT2cNOMX

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right ureter:

- no tumor identified

BFS: Left ureter:

- no tumor identified

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right ureter." It consists of a segment of pink-tan ureter measuring 0.7 x 0.5 x 0.1 cm. Entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left ureter." It consists of a segment of ureter measuring 0.7 x 0.7 x 0.4 cm. Entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Prostate, Bladder." It consists of a bladder with associated prostate measuring overall 17 x 14 x 4.5 cm. The peritoneum measures 13 x 11 x 0.5 cm. The bladder measures 6.5 x 4 x 3 cm. Opening of the prostate and the bladder anteriorly reveals a pink-tan, fungating mass measuring 3 x 2.2 x 1 cm, located at the mid to left bladder, near the trigone region. The tumor grossly invades the muscularis propria into the pericystic adipose tissue, and is 2.5 cm from the black inked surgical margin. There is a green-yellow necrotic ulcerative region measuring 4 x 2 x 0.3 cm adjacent to the mass lesion. The remainder of the bladder mucosa shows focal erythematous, edematous area. The wall of the bladder measures 1.1 cm in thickness. The right ureter measures 4 cm in length by 0.5 cm in diameter and appear to be dilated. The left ureter measures 2 cm in length by 0.5 cm in diameter. The prostate measures 5 x 4 x 4 cm. The prostatic urethra measures 3 cm in length by 2 cm in circumference. The verumontanum measures 1.8 x 0.3 x 0.1 cm. The right vas deferens measures 4.5 cm in length by 0.6 cm in diameter, and the left vas deferens measures 2.5 cm in length by 0.5 cm in diameter. The right seminal vesicle measures 3 x 1.5 x 0.7 cm, and the left seminal vesicle measures 3 x 2 x

[page 3 of 5]
REPORT

Collected

Ordered by

0.5 cm. Sectioning of the prostate reveals pink-tan, nodular cut surface. Representative sections are submitted in a total of 24 cassettes.

D: The specimen is received in formalin and labeled "Lymph node of cloquet, left." It consists of a fragment of yellow-tan tissue measuring 2 x 1.2 x 0.8 cm. One lymph node measuring 0.8 cm in greatest dimension is identified. This lymph node is bisected and the specimen is entirely submitted in one cassette.

E: The specimen is received in formalin and labeled "Obturator lymph node left." It consists of multiple fragments of yellow-tan, soft tissue measuring 6 x 4 x 2 cm in aggregate. Multiple lymph nodes are identified with the largest one measuring 2.8 cm in greatest dimension. The largest lymph node is bisected and the specimen is entirely submitted in three cassettes.

F: The specimen is received in formalin and labeled "Hypogastric lymph node left." It consists of a fragment of yellow-tan, soft tissue measuring 5 x 2 x 0.8 cm. One lymph node is identified measuring 3 cm in greatest dimension. The lymph node is bisected and the specimen is entirely submitted in one cassette.

G: The specimen is received in formalin and labeled "Presacral lymph node." It consists of a fragment of pink-tan, soft tissue measuring 2 x 1 x 0.5 cm. Two lymph nodes are identified with the largest one measuring 0.7 cm in greatest dimension. Entirely submitted in one cassette.

H: The specimen is received in formalin and labeled "Left common iliac lymph node." It consists of a fragment of pink-tan, soft tissue measuring 2.2 x 1 x 0.5 cm. The specimen is entirely submitted in one cassette.

I: The specimen is received in formalin and labeled "Right cloquet lymph node." It consists of a fragment of yellow-tan, soft tissue measuring 3 x 2 x 1 cm. Two possible lymph nodes are identified with the largest one measuring 1.8 cm in greatest dimension. The lymph nodes are bisected and the specimen is entirely submitted in one cassette.

J: The specimen is received in formalin and labeled "Right obturator lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 7 x 5 x 1 cm in aggregate. One lymph nodes is identified which measures 3 cm in greatest dimension. The specimen is entirely submitted in three cassettes.

K: The specimen is received in formalin and labeled "Right external iliac lymph node." It consists of a fragment of yellow-tan soft tissue measuring 3 x 1.5 x 0.5 cm. One lymph node is identified measuring 2.5 cm in greatest dimension. The lymph node is bisected and the specimen is entirely submitted in one cassette.

L: The specimen is received in formalin and labeled "Right hypogastric lymph node." It consists of a fragment of yellow-tan soft tissue measuring 2 x 1 x 0.5 cm. The specimen is entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "Right common iliac lymph node." It consists of a fragment of yellow-tan soft tissue measuring 2 x 1 x 1 cm. One lymph node is identified which measures 0.9 cm in greatest dimension. The lymph node is bisected and the specimen is entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Left proximal ureter." It consists of a segment of ureter measuring 1.5 cm in length by 0.5 cm in diameter. Two metallic clips closest to the proximal margin are identified. The proximal margin is submitted in one cassette.

O: The specimen is received in formalin and labeled "Right proximal ureter." It consists of a segment of ureter measuring 1.6 cm in length by 0.7 cm in diameter.

[page 4 of 5]
Collected

Ordered by

Two metallic clips are located closest to the proximal margin. The proximal margin is submitted in one cassette.

SECTIONS:

AFS: frozen section, right ureter
BFS: frozen section, left ureter
C1: right ureter, distal margin
C2,3: prostate apex
C4: right vas deferens and seminal vesicle
C5: left vas deferens and seminal vesicle
C6-10: mass lesion
C11: left lateral
C12: left dome
C13: right dome
C14: right lateral
C15: right trigone
C16: right ureteral distal margin
C17: right distal prostate
C18: left distal prostate
C19: right midprostate
C20: left midprostate
C21: right midprostate, serially sectioned
C22: left midprostate, serially sectioned
C23: right proximal prostate
C24: left proximal prostate
D: lymph node of Cloquet, left
E1: one lymph node, bisected
E2,3: possible lymph nodes
F: hypogastric lymph node, left
G: presacral lymph node
H: left common iliac lymph node
I: right lymph node of Cloquet
J1: one lymph node, bisected
J2,3: possible lymph nodes
K: right external iliac lymph node
L: right hypogastric lymph node
M: right common iliac lymph node
N: left proximal ureter
O: right proximal ureter

MICROSCOPIC DESCRIPTION:

A-B: See final microscopic-diagnosis.

C: Sections of the fungating seen grossly on the left posterior trigone region of bladder corresponding histologically to a poorly differentiated invasive transitional cell carcinoma, grade 4/4 (C6-10). The neoplastic cells have high N/C ratios with large pleomorphic nuclei and are arranged in solid sheets. The cytoplasm shows clear cell change. There is focal squamous metaplasia present as well as frequent mitosis. A moderate inflammatory response to the tumor is noted. The tumor extends through the muscularis propria. The radial inked resection margins are free of tumor. No associated transitional cell carcinoma in situ identified. No definitive lymphovascular space invasion is seen.

Sections of the prostate show extensive neoplastic process involving the right and left lobes from distal to proximal (C17-20,24). The tumor is characterized predominantly by irregularly shaped and variably sized malignant glands that randomly infiltrate the stroma. A small component of the tumor show malignant gland fusion. The neoplastic cells are medium to large with high nuclear to cytoplasmic ratios, vesicular chromatin and prominent nucleoli. The prostatic

[page 5 of 5]
Collected:

Ordered by:

capsule is free of tumor. There are multifocal areas of perineural invasion. No lymphovascular space invasion identified. Bilateral seminal vesicles and vasa deferentia are free of tumor. Apical margin is free of tumor. In addition to invasive carcinoma, the prostatic parenchyma shows high grade prostatic intraepithelial neoplasia (PIN III) characterized by hyperplastic glands lined by stratified layers of enlarged cells with large nuclei and prominent nucleoli.

D-O: See final microscopic-diagnosis.

Signed by:

ELECTRONIC SIGNATURE

POST-OPERATIVE DIAGNOSIS:

Same

PRE-OPERATIVE DIAGNOSIS:

Bladder TCC

ORDERING PHYSICIAN:

Ordering Physician:

Source: NCI Genomic Data Commons file ef76fc0b-fb9e-4d0e-9973-098b6e008a9b (TCGA-XF-A8HF.1276CC52-8D49-40E9-A365-3E065E1B77EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).